Surgical pathology report (de-identified scan), TCGA case TCGA-2L-AAQI, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Technical University of Munich, specimen TCGA-2L-AAQI-01A (Primary Tumor).

[page 1 of 3]
Age: male

Surgery date:

Macroscopic evaluation

1. Liver biopsy (segment 2/3): unfixed, a spindle-like specimen from the liver, max. 1.2x0.6x0.5 cm. Obviously intact fine capsule. At margins the liver parenchyma homogenous brownish. Complete for instantaneous section after cutting into two halves. Ink mark: black = resection margin deep and lateral parenchymatous.
2. Arteria mesenterica superior: unfixed, 4 irregular yellowish tissue lamellae, max. 1.6 cm, therein several small knots up to max. 0.6 cm. The small knots used for instantaneous section.
3. Lymph node pancreas upper rim: unfixed, two irregular fatty tissue lamellae, max. 3.2 cm, therein an encapsulated lymph node of max. 1.2 cm. The lymph node is cut into two halves and sent to instantaneous section.
4. Edge of the pancreas: unfixed, a max. 2.5 cm in diameter and max. 0.4 cm thick lamellae of pancreas parenchyma with central D. pancreaticus of max. 0.5 cm. Complete for instantaneous section.
5. Tissue at Arteria mesenterica superior: unfixed, two irregular, max. 3.8 cm in diameter tissue lamellae, partially indurated in max. 1.2 cm areas. Representative portions from the indurated areas are used for instantaneous section. Remaining tissue for paraffin embedding.
6. Lymph node Lig. Hepatoduodenale: fixed, 10 g fragmented, lipomatous tissue with definable knot-like structures, max. 1 cm.
7. Gall bladder: fixed, a well filled 10x5x5 cm large gall bladder with mirroring serosa. D. cysticus resected after 1.5 cm. The mucosa is green velvet-like.
8. Tissue at A. mesenterica superior: fixed, 6 g fragmented lipomatous tissue, max. 0.5 cm. Completely embedded.
9. Whipple specimen: fixed, a pancreatic head resection specimen, composed of a 5x4x5 cm (heightxwidthxdepth) large pancreatic head and a c-shaped portion of duodenum/jejunum, 25 cm long. Further attached an omentum, partially resected 11x6x1.5 cm. Within the pancreatic parenchyma at the Proc. uncinatus a 4x3x3 cm large solid, grey/glass-like partially well-defined knot with white-yellow margin, partially fine cystic areas. The tumor extends into the fatty tissue towards dorsal, medial, and ventral, forming an edge at the medial resection margin. The remaining pancreatic parenchyma grey/glass-like fibrotic, only partially at the resection margin regularly lobulated pancreatic parenchyma with fibrotic parts.
- A. Tumor in relation to resection margin ventral, medial
- B. Tumor in relation to the resection margin medial
- C. additional reference section tumor in relation to resection margin medial
- D. Tumor in relation to resection margin dorsal
- E.-F. additional reference sections pancreas
- G. papillae
- H. Resection margin bile duct
- J. resection margin pancreas
- K. resection margin duodenum
- L. resection margin duodenum
- M. Lymph node peripancreatic above of the papillae
- N. large lymph node peripancreatic above the papillae
- O. lymph node peripancreatic below the papillae ventral and medial
- P. lymph node peripancreatic, below the papillae dorsal
- Q. Omentum
10. resection margin bile duct: fixed, a bile duct specimen, 1 cm in diameter, 0.5 cm long

ICD-O-3

Adenocarcinoma, duct NOS 8500/3
Site: Pancreas head C25.0
J20 6/5/14

[page 2 of 3]
Instantaneous section report

1. Using instantaneous section no evidence for malignancy. There is cholestasis, moderate portal inflammation and moderate mixed drop-like adiposis. No evidence for a metastasis (clinically suspected pancreas head carcinoma).
2. Using instantaneous section detection of an intranodal lymph node metastasis of a mucus forming adenocarcinoma, two lymph nodes in total. The findings morphologically in line with a pancreas carcinoma.
3. Lymph node without tumor
4. Resection margin of the pancreas parenchyma is without tumor, no evidence for malignancy. Low grade PanIN
5. Positive malignancy, there is extensive perineural invasion

Processed: 27 blocks, instantaneous sections, H&E

Microscopy

1. Using paraffin embedded material no evidence for tumor. There is a moderate mixed/drop-like adiposis and a clear cholestasis. To answer possible fibrosis additional stainings are being done.
2. Using paraffin material detection of a lymph node metastasis of a mucus-forming moderately differentiated adenocarcinoma.
3. Using paraffin material lymph node without tumor.
4. Using paraffin material parenchymatous resection margin without tumor, the D. pancreaticus with PanIN 1b. Focally chronic pancreatitis with atrophic lobules and reactive epithelia of the duct.
5. Using paraffin material soft tissue with wide carcinoma infiltrates and perineural growth pattern
6. Five lymph nodes without tumor.
7. Gall bladder mucosa with fine villi, the epithelium regular. No tumor, no inflammation.
8. fatty tissue with nerve structures, with a clear extension of carcinoma and a lymph node with a small focus
9. The macroscopically described tumor is histologically a mucus-forming adenokarzinoma, which shows partially a strong cell and nuclear pleomorphism, frequent bright cellular tumor complexes and bizarre nuclear structures, partially dissolute tumor growth, extensive stromal desmoplasia. Massive perineural invasion. Tumor infiltration within the peripancreatic fatty tissue. Infiltration of the duodenal wall musculature at the papillae. Here severe nuclear atypia in line with PanIN grade 3 in the preexisting duct epithelium of D. pancreaticus and lateral ducts. Safety margins to the resection margins towards medial and dorsal < 0.1 cm, towards ventral 0.2 cm. At the peripancreatic resection margin no evidence of tumor, too, the epithelium of the D. pancreaticus with PanIN 1b. The resection margins in the duodenum without tumor. Identification of 5 lymph node metastases out of 11 lymph nodes. The omentum is without tumor.
10. Rim of the bile duct is without tumor.

Short report on diagnostic findings

1. Liver biopsy (segment 2/3) with moderate hepatocellular lipomatosis (appr. 40%) and cholestasis. EvG stain shows only a low portal fibrosis. The iron and PAS stains shown no alterations.
- 2.-6., 8.-10. Poorly differentiated ductal adenocarcinoma of the pancreatic head, max. 4 cm large, with infiltration into the duodenal wall and the peripancreatic fatty tissue, reaching the Arteria mesenterica superior. Extensive perineural growth. Identification of a PanIN 3 within the preexisting epithelium of the D. pancreaticus and the lateral branches. Safety margin towards dorsal and medial < 0.1 cm, but presence of tumor at the Arteria mesenterica superior and in the corresponding additional resection specimen. Identification of 6 lymph node metastases. Resection margins at pancreas parenchyma, D. choledochus, and duodenum are all without tumor.
7. Gall bladder without pathological findings.

[page 3 of 3]
TNM classification (UICC, 7th Edition 2010): pT3, N1 (6/19), G3, R1

Source: NCI Genomic Data Commons file 63a199ce-690a-4c6a-bb8d-b5874d7f2935 (TCGA-2L-AAQI.25ED4E79-E39F-43A7-B2C1-94650C0F22A1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).